Somatic mutation profile of tumor specimen TCGA-FG-A6IZ-01A (aliquot TCGA-FG-A6IZ-01A-11D-A31L-08) from TCGA case TCGA-FG-A6IZ, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 61.0 years (22,275 days).
Specimen TCGA-FG-A6IZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8493d184-6e0f-45cd-bc52-c159c53965a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-A6IZ-10A (Blood Derived Normal), aliquot TCGA-FG-A6IZ-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6b41127-ce08-4184-82ab-3b5d90ea6800

The open-access MAF lists 51 somatic variants for this specimen: 39 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 34, Silent 12, Splice Site 2, Nonsense Mutation 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.4535G>T p.R1512L | Missense Mutation (SNP) | VAF 65/73 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV50554672, COSV50623937; called by muse, mutect2, varscan2
- DNM1L | c.346_347del p.E116Kfs*6 | Frame Shift Del (DEL) | VAF 19/46 reads (41%) | catalogued as rs879255687; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 27/80 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS20 | c.295T>C p.F99L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101239230; called by muse, mutect2
- ARHGEF3 | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); catalogued as COSV99575275; called by muse, mutect2, varscan2
- ARID2 | c.5132A>T p.Q1711L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV100536059; called by muse, mutect2, varscan2
- CATSPERB | c.2377G>A p.A793T | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV99831209; called by muse, mutect2
- CCDC22 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100544731, COSV100545466; called by muse, mutect2, varscan2
- CDKN1A | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 52/424 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1489071647, COSV55191470; called by muse, mutect2, varscan2
- CNTN3 | c.2221C>T p.R741C | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747484787, COSV55161998; called by muse, mutect2, varscan2
- CNTN6 | c.2581G>A p.V861I | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as rs777207776, COSV63181945; called by muse, mutect2, varscan2
- COL9A1 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as rs1165032530, COSV100294698, COSV100294893; called by muse, mutect2, varscan2
- CUL5 | c.1168A>G p.K390E | Missense Mutation (SNP) | VAF 55/262 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.433); catalogued as COSV101263668; called by muse, mutect2, varscan2
- E4F1 | c.190C>G p.Q64E | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as COSV100065681; called by muse, mutect2, varscan2
- FREM1 | c.1442T>C p.V481A | Missense Mutation (SNP) | VAF 143/154 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66533483; called by muse, mutect2, varscan2
- GNAT3 | c.415T>C p.C139R | Missense Mutation (SNP) | VAF 70/187 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1464134120, COSV101242383; called by muse, mutect2, varscan2
- IKBKB | c.202C>T p.L68= | Splice Region (SNP) | VAF 21/40 reads (53%) | catalogued as rs1440778745, COSV100645686; called by muse, mutect2, varscan2
- LAMA3 | c.8500G>A p.G2834S (on ENST00000313654 / NM_198129.4; = p.G1225S on NM_000227.6) | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1154233; ClinVar: benign; called by muse, mutect2
- LRRC3 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1289907108, COSV52399195; called by muse, mutect2, varscan2
- PHF8 | c.2851C>G p.L951V (on ENST00000357988 / NM_001184896.1; = p.L915V on NM_015107.3) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV100154126; called by muse, mutect2
- POGLUT1 | c.20C>G p.S7W | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV99809568; called by muse, mutect2, varscan2
- POU4F3 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100047026; called by mutect2, varscan2
- R3HDM1 | c.2485G>A p.G829R | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1053999323, COSV51527064; called by muse, mutect2, varscan2
- SIRPA | c.1088A>G p.E363G | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100605163; called by muse, mutect2
- SLC16A6 | c.1195A>G p.I399V | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100517294; called by muse, mutect2, varscan2
- SLC5A11 | c.372+2T>G p.X124_splice | Splice Site (SNP) | VAF 16/363 reads (4%) | catalogued as rs1268088418, COSV100762771; called by muse, mutect2
- SLC9C2 | c.1131G>A p.W377* | Nonsense Mutation (SNP) | VAF 99/225 reads (44%) | catalogued as COSV100876735; called by muse, mutect2, varscan2
- SLFN12 | c.1628C>A p.S543Y | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV100513060; called by muse, mutect2, varscan2
- SOX4 | c.352A>G p.K118E | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV99782004; called by muse, mutect2, varscan2
- SPTY2D1 | c.1039C>T p.H347Y | Missense Mutation (SNP) | VAF 35/304 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100311648; called by muse, mutect2, varscan2
- SREBF1 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV99888770; called by muse, mutect2, varscan2
- ST3GAL3 | c.520C>T p.R174C (on ENST00000361392 / NM_174964.4; = p.R159C on NM_006279.5) | Missense Mutation (SNP) | VAF 50/57 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1558784546, COSV99495296; called by muse, mutect2, varscan2
- TAF4B | c.598-1G>A p.X200_splice | Splice Site (SNP) | VAF 14/110 reads (13%) | catalogued as rs1270073306, COSV99300169; called by mutect2, varscan2
- TMC2 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs372275239; called by muse, mutect2
- TPP2 | c.1238G>A p.G413E | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101060250; called by muse, mutect2, varscan2
- TRIM71 | c.2027G>A p.R676H | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101070426; called by muse, mutect2
- UBE3C | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100779929; called by muse, mutect2, varscan2
- XDH | c.3008C>T p.P1003L | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101052184; called by muse, mutect2
- YPEL3 | c.56G>A p.R19Q (on ENST00000398838 / NM_001145524.2; = p.R57Q on NM_031477.5) | Missense Mutation (SNP) | VAF 82/191 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as rs374762947, COSV54221187; called by muse, mutect2, varscan2
- AADACL3 | c.702G>A p.S234= | Silent (SNP) | VAF 53/220 reads (24%) | catalogued as rs375207083; called by muse, mutect2, varscan2
- AFTPH | c.2175G>A p.K725= | Silent (SNP) | VAF 11/139 reads (8%) | catalogued as COSV99480661; called by muse, mutect2
- CBL | c.228G>A p.A76= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as COSV99876195; called by muse, mutect2, varscan2
- EGR4 | c.714T>C p.D238= (on ENST00000545030; = p.D135= on NM_001965.4) | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV101474239; called by muse, mutect2
- GPR149 | c.1647T>C p.I549= | Silent (SNP) | VAF 48/220 reads (22%) | catalogued as COSV101078401; called by muse, mutect2, varscan2
- JAG1 | c.3570G>A p.P1190= | Silent (SNP) | VAF 19/385 reads (5%) | catalogued as rs201572666; ClinVar: benign / uncertain significance; called by muse, mutect2
- PAPPA2 | c.102G>A p.L34= | Silent (SNP) | VAF 42/155 reads (27%) | catalogued as COSV100866764; called by muse, mutect2, varscan2
- SLC12A6 | c.2964C>T p.Y988= (on ENST00000354181 / NM_001365088.1; = p.Y937= on NM_005135.2) | Silent (SNP) | VAF 53/127 reads (42%) | catalogued as rs1255615487, COSV51628796; called by muse, mutect2, varscan2
- SPART | c.1335T>C p.T445= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV100768716; called by muse, mutect2, varscan2
- TECRL | c.171G>A p.T57= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV67090843; called by muse, mutect2, varscan2
- YEATS2 | c.2610G>A p.Q870= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV100527763; called by muse, mutect2, varscan2
- ZNRF4 | c.672C>T p.V224= | Silent (SNP) | VAF 12/159 reads (8%) | catalogued as COSV99706491; called by muse, mutect2
